Somatic mutation profile of tumor specimen TCGA-OR-A5JP-01A (aliquot TCGA-OR-A5JP-01A-11D-A29I-10) from TCGA case TCGA-OR-A5JP, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 40.2 years (14,667 days).
Specimen TCGA-OR-A5JP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25774f5f-5d47-412b-936b-97fa48a6d483.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5JP-10A (Blood Derived Normal), aliquot TCGA-OR-A5JP-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/432df57a-7516-4cdd-8f60-54f9c28cec56

The open-access MAF lists 75 somatic variants for this specimen: 57 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 17, Frame Shift Ins 4, Frame Shift Del 3, Nonsense Mutation 3, Splice Region 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMPH | c.1213C>G p.Q405E | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.695); catalogued as COSV100343998; called by muse, varscan2
- ART3 | c.1147A>G p.I383V (on ENST00000355810 / NM_001377173.1; = p.I372V on NM_001179.6) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1315644943; called by muse, mutect2
- ASPRV1 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.896); catalogued as rs747852584, COSV57228976; called by muse, mutect2, varscan2
- BICC1 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 25/480 reads (5%) | catalogued as COSV65862647; called by muse, mutect2
- BPIFB6 | c.856C>A p.L286M | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs1396516992; called by muse, mutect2
- CEP128 | c.2839G>A p.E947K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV55388163; called by muse, mutect2, varscan2
- CHRNA5 | c.982A>G p.I328V | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.961); catalogued as rs1250686051; called by muse, varscan2
- CYP4F8 | c.1168C>T p.R390W | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1419560498, COSV100358244; called by muse, mutect2, varscan2
- ETV1 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54136760, COSV54140570; called by muse, mutect2
- F13A1 | c.1556T>C p.V519A | Missense Mutation (SNP) | VAF 78/288 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1224605741; called by muse, mutect2, varscan2
- GFUS | c.729C>T p.S243= | Splice Region (SNP) | VAF 45/197 reads (23%) | catalogued as rs775618049; called by muse, mutect2, varscan2
- GIPC1 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 38/288 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs1419352802; called by muse, mutect2, varscan2
- LCT | c.684G>C p.E228D | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1237651297, COSV51543939; called by muse, mutect2, varscan2
- LRRC7 | c.1898G>A p.R633H (on ENST00000651989 / NM_001370785.2; = p.R600H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs375559029, COSV50533887; called by muse, mutect2, varscan2
- NOTCH4 | c.4679C>T p.A1560V | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs967436228, COSV66683869, COSV66684483; called by muse, mutect2, varscan2
- PCBP2 | c.524dup p.K176Efs*46 | Frame Shift Ins (INS) | VAF 15/70 reads (21%) | catalogued as rs776329515; called by mutect2, varscan2
- PPRC1 | c.3001C>G p.P1001A | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53384088; called by muse, mutect2, varscan2
- RPRD2 | c.3316G>A p.V1106I | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.349); catalogued as rs1202684003, COSV64822629; called by muse, mutect2, varscan2
- SEC22A | c.789C>G p.I263M | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as rs1262481244; called by muse, mutect2, varscan2
- ZNF804B | c.2306T>C p.I769T | Missense Mutation (SNP) | VAF 61/198 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100304219; called by muse, mutect2, varscan2
- C19orf57 | c.1145G>A p.R382K | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- C1orf87 | c.915G>T p.L305F | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- C21orf62 | c.292C>G p.L98V | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- CCR3 | c.271A>C p.I91L | Missense Mutation (SNP) | VAF 101/266 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- CDH4 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- COL11A1 | c.1286G>C p.G429A | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DOCK10 | c.2095_2096del p.C699Hfs*2 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | called by pindel, varscan2
- ECE1 | c.432_433dup p.R145Hfs*28 | Frame Shift Ins (INS) | VAF 71/295 reads (24%) | called by mutect2, pindel, varscan2
- ENPEP | c.733A>G p.I245V | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- FBXO9 | c.1091T>G p.L364R | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FDXR | c.302A>G p.H101R | Missense Mutation (SNP) | VAF 81/377 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPATCH8 | c.1505_1510del p.V502_S503del | In Frame Del (DEL) | VAF 18/63 reads (29%) | called by mutect2, pindel, varscan2
- IBTK | c.2309T>G p.V770G | Missense Mutation (SNP) | VAF 62/269 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGA3 | c.3119A>C p.Q1040P | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.009); called by muse, mutect2
- MLIP | c.1205C>T p.T402I | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- NELL1 | c.1512C>A p.C504* | Nonsense Mutation (SNP) | VAF 32/249 reads (13%) | called by muse, mutect2, varscan2
- NF1 | c.6463G>T p.E2155* (on ENST00000358273 / NM_001042492.3; = p.E2134* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 29/43 reads (67%) | called by muse, mutect2, varscan2
- OR2S2 | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OVCH1 | c.2729A>G p.E910G | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- PCK1 | c.83G>C p.R28T | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- PELP1 | c.1440dup p.S481Efs*3 | Frame Shift Ins (INS) | VAF 6/38 reads (16%) | called by mutect2, pindel
- PIK3AP1 | c.1135G>T p.A379S | Missense Mutation (SNP) | VAF 55/275 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRB3 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RAD50 | c.2675_2676del p.V892Gfs*5 | Frame Shift Del (DEL) | VAF 34/150 reads (23%) | called by pindel, varscan2
- RBM27 | c.1444G>C p.D482H | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- RRAGB | c.592C>G p.R198G (on ENST00000262850 / NM_016656.4; = p.R170G on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC2A12 | c.52A>T p.T18S | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- STX19 | c.533C>G p.S178C | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- TBPL2 | c.545C>A p.S182Y | Missense Mutation (SNP) | VAF 35/313 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- TDO2 | c.415G>C p.D139H | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- TP53 | c.1011_1015dup p.E339Afs*8 | Frame Shift Ins (INS) | VAF 23/96 reads (24%) | called by mutect2, varscan2
- TUT7 | c.1165_1166del p.F389Pfs*3 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- UBR4 | c.1198G>T p.G400C | Missense Mutation (SNP) | VAF 17/214 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- USP10 | c.2103C>G p.I701M | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.07); called by muse, mutect2
- VN1R2 | c.962T>G p.V321G | Missense Mutation (SNP) | VAF 49/372 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZBTB21 | c.1675G>C p.A559P | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZMIZ2 | c.1135A>T p.T379S | Missense Mutation (SNP) | VAF 41/294 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AHNAK2 | c.6501C>G p.A2167= | Silent (SNP) | VAF 88/206 reads (43%) | called by muse, mutect2, varscan2
- CYP2C8 | c.972G>A p.Q324= | Silent (SNP) | VAF 40/201 reads (20%) | catalogued as rs529746836; called by muse, mutect2, varscan2
- FREM2 | c.8754T>C p.F2918= | Silent (SNP) | VAF 17/120 reads (14%) | catalogued as rs1248516608; called by muse, mutect2, varscan2
- HECTD4 | c.3540C>A p.R1180= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as COSV61179259; called by muse, mutect2, varscan2
- KCNG4 | c.1078C>T p.L360= | Silent (SNP) | VAF 88/338 reads (26%) | called by muse, mutect2, varscan2
- KIF11 | c.2067A>G p.L689= | Silent (SNP) | VAF 16/216 reads (7%) | called by muse, mutect2
- MYBPC1 | c.1212A>G p.G404= (on ENST00000550270 / NM_206820.2; = p.G429= on NM_002465.4) | Silent (SNP) | VAF 20/113 reads (18%) | catalogued as rs768659618; called by muse, mutect2, varscan2
- NF2 | c.795G>A p.S265= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs376609988; called by muse, mutect2, varscan2
- PDLIM4 | c.924G>A p.A308= | Silent (SNP) | VAF 50/189 reads (26%) | catalogued as rs1140552; called by muse, mutect2, varscan2
- PYGM | c.1923C>T p.L641= | Silent (SNP) | VAF 47/186 reads (25%) | catalogued as COSV51218010; called by muse, mutect2, varscan2
- RIOX1 | c.1575G>T p.G525= | Silent (SNP) | VAF 30/132 reads (23%) | called by mutect2, varscan2
- SOX10 | c.438C>T p.N146= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as rs766407815; called by mutect2, varscan2
- TGFB3 | c.135A>C p.G45= | Silent (SNP) | VAF 56/306 reads (18%) | called by muse, mutect2, varscan2
- TIE1 | c.2346C>A p.T782= | Silent (SNP) | VAF 24/296 reads (8%) | called by muse, mutect2
- TMEM104 | c.312C>T p.Y104= | Silent (SNP) | VAF 41/188 reads (22%) | catalogued as rs1441160808, COSV59110349; called by muse, mutect2, varscan2
- TMEM214 | c.267G>A p.K89= | Silent (SNP) | VAF 39/207 reads (19%) | called by muse, mutect2, varscan2
- TNRC6C | c.2826G>C p.R942= | Silent (SNP) | VAF 26/327 reads (8%) | called by muse, mutect2
- SEH1L | c.*1743C>A | 3'UTR (SNP) | VAF 23/58 reads (40%) | called by muse, mutect2, varscan2
